Gene-level copy-number profile of tumor specimen C3N-02379-01 (profiled together with C3N-02379-02) from CPTAC case C3N-02379, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 57.0 years (20,827 days).
Specimen C3N-02379-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04716ed1-258a-4031-bf5a-5feb3cc9a1a8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02379-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/d5f45b0e-bd62-46aa-88e4-77821631241e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 4,862; copy number 2: 25,931; copy number 3: 21,069; copy number 4: 5,153; copy number 5: 422; copy number 6: 168; copy number 7: 291; copy number 8: 57; copy number 9: 60; copy number 11: 49; copy number 12: 160; copy number 13: 5; copy number 14: 8; copy number 15: 7; copy number 16: 3; copy number 17: 3; copy number 20: 4; copy number 22: 19; copy number 24: 12; copy number 26: 9; copy number 28: 3; copy number 30: 1; copy number 32: 7.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,874,793–143,905,966, 3 genes (within-gene range 0–2): FCGR1CP, H2BP2, H3-2.
- chr2:89,906,757–89,969,335, 6 genes: IGKV3D-34, IGKV1D-33, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27.
- chr2:90,038,848–90,083,291, 5 genes: IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17.
- chr2:90,114,838–90,122,564, 2 genes (within-gene range 0–2): IGKV3D-15, IGKV2D-14.
- chr2:90,179,889–90,235,370, 5 genes: IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr9:9,442,060–9,803,784, 2 genes (within-gene range 0–2): RN7SL5P, AL513422.1.
- chr9:21,077,104–23,956,444, 66 genes (broad region; genes not listed).
- chr21:44,133,610–44,210,114, 1 gene (within-gene range 0–4): GATD3A.
- chr22:18,178,038–18,404,206, 5 genes: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3.
- chr22:18,486,999–18,491,247, 1 gene (within-gene range 0–3): AC023490.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,217 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,784,376–143,797,108, 3 genes, copy number 5: AC239800.3, LINC02591, RNU1-143P.
- chr4:34,966,241–45,051,652, 153 genes, copy number 5–8 (broad region; genes not listed).
- chr7:50,274,790–57,227,066, 151 genes, copy number 9–32 (broad region; genes not listed).
- chr7:65,773,620–65,859,766, 4 genes, copy number 7–8: GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P.
- chr7:148,983,755–149,424,890, 20 genes, copy number 5: RNY3, RNY1, GHET1, PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1.
- chr8:90,791,741–90,959,393, 1 gene, copy number 6 (within-gene range 3–6): NECAB1.
- chr8:90,958,471–91,398,155, 10 genes, copy number 6: C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7.
- chr8:94,249,253–109,334,121, 267 genes, copy number 6–17 (within-gene range 3–17) (broad region; genes not listed).
- chr8:109,573,978–111,757,710, 19 genes, copy number 5–9 (within-gene range 2–9): SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P.
- chr8:115,408,496–129,683,770, 193 genes, copy number 5–13 (broad region; genes not listed).
- chr8:142,111,414–142,209,003, 3 genes, copy number 15: AC103758.1, MIR4472-1, LINC00051.
- chr9:29,254,075–29,826,711, 4 genes, copy number 20: AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr9:42,725,013–60,964,196, 19 genes, copy number 5: BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:61,581,813–61,582,675, 1 gene, copy number 12: AL935212.3.
- chr10:42,979,017–42,997,681, 2 genes, copy number 5: LINC01264, MIR5100.
- chr10:43,371,636–43,525,217, 7 genes, copy number 7: FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2.
- chr11:66,435,075–68,272,001, 103 genes, copy number 12–15 (broad region; genes not listed).
- chr11:68,891,276–70,436,584, 49 genes, copy number 5–11: MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:67,610,986–68,987,463, 39 genes, copy number 6: AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2, RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P, ZFP36L1, MAGOH3P, BLZF2P, ACTN1, HMGN1P3, BANF1P1, ACTN1-AS1.
- chr17:80,260,866–83,240,804, 164 genes, copy number 5 (broad region; genes not listed).
- chr20:62,143,769–62,203,568, 2 genes, copy number 8: SS18L1, MTG2.
- chr22:18,733,914–18,843,399, 3 genes, copy number 5 (within-gene range 2–5): FAM230E, GGT3P, AC008132.2.

Autosomal genes at a single copy (total copy number 1): 4,862. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
